Somatic mutation profile of tumor specimen RC-B6E3-TBP1-A (aliquot RC-B6E3-TBP1-A-1-0-D-A93N-47) from RC case RC-B6E3, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants); Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,869 days).
Specimen RC-B6E3-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2edaf4a-d5a6-418d-b0c3-dd396c05b836.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6E3-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B6E3-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70c22e6e-9df4-465f-a5b0-82619433886d

The open-access MAF lists 85 somatic variants for this specimen: 58 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 23, Nonsense Mutation 3, Splice Region 3, RNA 2, Frame Shift Ins 2, 5'UTR 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs964127282, COSV53973119; called by muse, mutect2, varscan2
- ADGB | c.4951A>G p.K1651E | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs753511760; called by muse, mutect2, varscan2
- AMPD1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs146437677; called by muse, mutect2, varscan2
- ANKRD36 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 139/164 reads (85%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs1261241604; called by muse, mutect2, varscan2
- ASB5 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs984972661; called by muse, mutect2, varscan2
- BEST2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as rs922110604; called by muse, mutect2, varscan2
- BTN1A1 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1309455178; called by muse, mutect2, varscan2
- CCR4 | c.993C>G p.Y331* | Nonsense Mutation (SNP) | VAF 55/231 reads (24%) | catalogued as COSV100447462, COSV58381294, COSV58381335; called by muse, mutect2, varscan2
- CFAP126 | c.171G>A p.K57= | Splice Region (SNP) | VAF 47/154 reads (31%) | catalogued as COSV61367606, COSV61368487; called by muse, mutect2, varscan2
- COL12A1 | c.6066G>A p.T2022= | Splice Region (SNP) | VAF 25/49 reads (51%) | catalogued as rs754929219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.3440T>C p.L1147P | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59401029; called by muse, mutect2, varscan2
- DNAH2 | c.7568G>A p.R2523Q | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs749633489, COSV66715812; called by muse, mutect2, varscan2
- FLRT2 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV58142228; called by muse, mutect2, varscan2
- FSTL5 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.1); catalogued as COSV60178875; called by muse, mutect2, varscan2
- GOLGA8K | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.521); catalogued as rs764243326; called by muse, mutect2, varscan2
- GPR25 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 189/309 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100421800; called by muse, mutect2, varscan2
- GRM5 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916429961; called by muse, mutect2, varscan2
- HCN3 | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 236/366 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as rs1470737272; called by muse, varscan2
- HNRNPA2B1 | c.182C>A p.S61* (on ENST00000354667 / NM_031243.3; = p.S49* on NM_002137.4) | Nonsense Mutation (SNP) | VAF 64/132 reads (48%) | catalogued as COSV61158479, COSV61159314; called by muse, mutect2, varscan2
- ITGB4 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs768219131; called by muse, mutect2, varscan2
- KCNH7 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59789396; called by muse, mutect2, varscan2
- ONECUT2 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 103/227 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1309677620; called by muse, mutect2, varscan2
- OR6K2 | c.970T>C p.F324L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | PolyPhen benign (0); catalogued as rs776096613; called by muse, mutect2, varscan2
- OR8J3 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550603090, COSV56879225; called by muse, mutect2, varscan2
- PITPNM1 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs202115767; called by muse, mutect2, varscan2
- SLC44A2 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59836476; called by muse, mutect2, varscan2
- TBL1XR1 | c.869C>G p.T290R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV70501103; called by muse, mutect2, varscan2
- TRPS1 | c.2176G>A p.G726S (on ENST00000220888 / NM_001330599.2; = p.G739S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV55227586; called by muse, mutect2, varscan2
- TTLL7 | c.1634A>C p.K545T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs374855272; called by muse, mutect2, varscan2
- ARHGAP36 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 102/110 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ASNS | c.1241T>G p.L414R | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C6 | c.1373A>G p.E458G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CA3 | c.245dup p.P83Sfs*20 | Frame Shift Ins (INS) | VAF 25/91 reads (27%) | called by mutect2, pindel, varscan2
- CD47 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKKL1 | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.019); called by muse, mutect2
- EEF1AKNMT | c.1665dup p.I556Yfs*20 (on ENST00000361735 / NM_015935.5; = p.I470Yfs*20 on NM_014955.3) | Frame Shift Ins (INS) | VAF 39/157 reads (25%) | called by mutect2, pindel, varscan2
- FBXO15 | c.1158T>A p.H386Q | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GATA3 | c.344del p.S115Tfs*80 | Frame Shift Del (DEL) | VAF 86/212 reads (41%) | called by mutect2, pindel, varscan2
- GFM1 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- GPR156 | c.1418T>A p.I473K | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HOXA11 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- KCP | c.2608T>A p.C870S (on ENST00000620378; = p.C930S on NM_001366122.1) | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KRT17 | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC4 | c.2543T>A p.V848D | Missense Mutation (SNP) | VAF 86/96 reads (90%) | SIFT tolerated (0.62); PolyPhen benign (0.11); called by muse, varscan2
- PDE4DIP | c.6533G>T p.R2178L | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SETX | c.2190T>G p.N730K | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SHH | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- SLC13A1 | c.485A>G p.E162G | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- SLC24A3 | c.903A>G p.A301= | Splice Region (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.1480T>G p.L494V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPECC1 | c.2711A>G p.K904R | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SVOPL | c.334G>A p.G112S (on ENST00000419765; = p.M1? on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE1 | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 73/80 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB45 | c.1321T>C p.S441P | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZC3H12A | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- ZNF662 | c.262T>G p.L88V | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF682 | c.1331A>C p.K444T | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ZNF831 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ANGPTL6 | c.63G>T p.R21= | Silent (SNP) | VAF 74/158 reads (47%) | called by muse, mutect2, varscan2
- BOC | c.1854C>T p.S618= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as rs760500732, COSV56355511; called by muse, mutect2, varscan2
- CCDC154 | c.1537C>A p.R513= | Silent (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2, varscan2
- CFAP47 | c.429T>A p.I143= | Silent (SNP) | VAF 36/36 reads (100%) | called by muse, mutect2, varscan2
- CHD5 | c.5151G>A p.T1717= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as rs770976829, COSV99313289; called by muse, mutect2, varscan2
- CHST8 | c.996C>T p.S332= | Silent (SNP) | VAF 102/207 reads (49%) | called by muse, mutect2, varscan2
- CORIN | c.1776T>C p.C592= | Silent (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2
- DCAF12L1 | c.363C>T p.F121= | Silent (SNP) | VAF 122/132 reads (92%) | catalogued as rs775537701, COSV64421979; called by muse, mutect2, varscan2
- DNAH17 | c.12969C>T p.A4323= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as rs145079602; called by muse, mutect2, varscan2
- DNAH5 | c.9213C>T p.H3071= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as rs563907105, COSV54216067; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF2B5 | c.1836C>T p.P612= (on ENST00000647909; = p.P604= on NM_003907.3) | Silent (SNP) | VAF 84/132 reads (64%) | called by muse, mutect2, varscan2
- FAM172A | c.666A>G p.E222= | Silent (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- FAM9A | c.918G>A p.E306= | Silent (SNP) | VAF 73/79 reads (92%) | called by muse, mutect2, varscan2
- FANCE | c.1470C>T p.A490= | Silent (SNP) | VAF 124/135 reads (92%) | called by muse, mutect2, varscan2
- GON4L | c.3507G>T p.A1169= | Silent (SNP) | VAF 68/243 reads (28%) | called by muse, mutect2, varscan2
- LAP3 | c.69G>A p.G23= | Silent (SNP) | VAF 59/151 reads (39%) | catalogued as rs1429012087; called by muse, mutect2, varscan2
- MYORG | c.537C>T p.G179= | Silent (SNP) | VAF 61/144 reads (42%) | catalogued as rs1422440223, COSV52628101; called by muse, mutect2, varscan2
- NAV3 | c.4566T>G p.T1522= | Silent (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- OSBPL5 | c.1758G>A p.S586= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as rs201454794, COSV99720284; called by muse, mutect2, varscan2
- RARA | c.369G>T p.T123= | Silent (SNP) | VAF 80/172 reads (47%) | called by muse, mutect2, varscan2
- SPARCL1 | c.60T>C p.N20= | Silent (SNP) | VAF 53/104 reads (51%) | catalogued as rs1445027415; called by muse, mutect2, varscan2
- TACC3 | c.2196G>A p.Q732= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs1245775495; called by muse, mutect2, varscan2
- VMP1 | c.1044G>A p.K348= | Silent (SNP) | VAF 56/103 reads (54%) | called by muse, mutect2, varscan2
- MGAM | c.4618+337A>G | Intron (SNP) | VAF 79/170 reads (46%) | called by muse, mutect2
- MST1L | n.1461C>T | RNA (SNP) | VAF 55/360 reads (15%) | catalogued as rs755072257; called by muse, mutect2, varscan2
- MUC19 | n.14799G>T | RNA (SNP) | VAF 88/184 reads (48%) | called by muse, mutect2
- ST3GAL6 | c.-321C>T | 5'UTR (SNP) | VAF 63/202 reads (31%) | called by muse, mutect2, varscan2
